Somatic mutation profile of tumor specimen C3N-00200-02 (aliquot CPT0017870006) from CPTAC case C3N-00200, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 71.9 years (26,248 days).
Specimen C3N-00200-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f3c2c64-dc9f-4fbe-8321-f30a7da68b02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00200-31 (Blood Derived Normal), aliquot CPT0028400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43709afb-b729-4866-a897-ad31521e8682

The open-access MAF lists 62 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, Nonsense Mutation 7, Intron 4, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.3682G>A p.V1228M | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs141672372; called by muse, mutect2, varscan2
- ARHGAP35 | c.2227G>T p.G743* | Nonsense Mutation (SNP) | VAF 36/141 reads (26%) | catalogued as COSV101351256, COSV101351651; called by muse, mutect2, varscan2
- CASKIN1 | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs747282431; called by muse, mutect2
- CHFR | c.1885G>A p.V629I (on ENST00000432561 / NM_001161345.1; = p.V588I on NM_018223.2) | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs761464761, COSV57175328; called by muse, mutect2, varscan2
- ESRRB | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 71/468 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370122804; called by muse, mutect2, varscan2
- FTCD | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754659947; ClinVar: uncertain significance; called by muse, mutect2
- ITGA2B | c.2557G>A p.G853R | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs571337941; called by muse, mutect2, varscan2
- LRRK2 | c.4165G>A p.V1389I | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs140743795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOGS | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768946970, COSV52029424; called by muse, mutect2, varscan2
- MYO18B | c.7142G>A p.R2381H | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as rs200567905; called by muse, mutect2, varscan2
- NAV1 | c.4685C>T p.T1562M | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs958041251, COSV99818022; called by muse, mutect2, varscan2
- NFATC3 | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 10/186 reads (5%) | catalogued as rs1337086135, COSV60472457; called by muse, mutect2
- PDE11A | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 13/142 reads (9%) | catalogued as rs762405282, COSV53687790; called by muse, mutect2
- PITX1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs766215212; called by muse, mutect2
- PTMS | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 11/202 reads (5%) | catalogued as rs1215012877, COSV52568579; called by muse, mutect2
- TBC1D12 | c.1559G>A p.W520* | Nonsense Mutation (SNP) | VAF 10/302 reads (3%) | catalogued as rs1258845493, COSV56552975; called by muse, mutect2
- TECTA | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as rs200340759, COSV50725210; called by muse, mutect2, varscan2
- TIGIT | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs376892258, COSV67328921; called by muse, mutect2, varscan2
- ARAP1 | c.2761C>A p.Q921K (on ENST00000393609 / NM_001040118.2; = p.Q676K on NM_015242.4) | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- C8orf48 | c.379A>C p.T127P | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CDK13 | c.2599A>G p.S867G | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CFHR4 | c.147A>C p.Q49H (on ENST00000367416 / NM_001201551.2; = p.Q50H on NM_006684.5) | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ELF3 | c.248dup p.N83Kfs*9 | Frame Shift Ins (INS) | VAF 28/261 reads (11%) | called by mutect2, pindel, varscan2
- HOMER1 | c.547T>C p.W183R | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IL1RL1 | c.1332C>A p.H444Q | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2
- KCNU1 | c.571A>G p.N191D | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- MISP | c.232T>G p.S78A | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2
- MYCBP2 | c.6337C>G p.P2113A (on ENST00000357337; = p.P2151A on NM_015057.5) | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK8 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 11/319 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0.01); called by muse, mutect2
- PIK3CA | c.1401T>G p.N467K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- PRDM15 | c.1858C>A p.H620N | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PSG5 | c.827A>C p.N276T | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PTEN | c.126_139del p.G44Qfs*3 | Frame Shift Del (DEL) | VAF 21/233 reads (9%) | called by mutect2, pindel
- RAPGEF2 | c.2923C>T p.R975* | Nonsense Mutation (SNP) | VAF 15/425 reads (4%) | called by muse, mutect2
- SACS | c.7850A>G p.Y2617C | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIX5 | c.740A>G p.N247S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- SSTR5 | c.757G>C p.V253L | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2
- TAF1 | c.1969_1971del p.D657del (on ENST00000373790 / NM_138923.4; = p.D678del on NM_004606.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 27/275 reads (10%) | called by mutect2, pindel, varscan2
- TAF4 | c.2107C>T p.Q703* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- ZNF335 | c.2013G>T p.K671N | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF500 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADAMTS16 | c.2115G>A p.S705= | Silent (SNP) | VAF 18/183 reads (10%) | catalogued as rs1030114079, COSV99943834; called by muse, mutect2, varscan2
- ANK1 | c.3189C>T p.F1063= | Silent (SNP) | VAF 24/540 reads (4%) | catalogued as rs1291901143, COSV55873095; called by muse, mutect2
- ANO3 | c.354C>T p.H118= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs771916231, COSV56795943; called by muse, mutect2
- BTN2A1 | c.399C>T p.Y133= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs751274196, COSV57005233; called by muse, mutect2, varscan2
- ELOVL6 | c.579G>A p.K193= | Silent (SNP) | VAF 39/350 reads (11%) | catalogued as rs1345607151; called by muse, mutect2, varscan2
- HFM1 | c.3006G>A p.T1002= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs773788286, COSV54023987, COSV99645186; called by muse, mutect2
- HTR3A | c.1431C>T p.Y477= | Silent (SNP) | VAF 67/453 reads (15%) | catalogued as rs139863344; called by muse, mutect2, varscan2
- IL4R | c.1599C>T p.V533= | Silent (SNP) | VAF 24/158 reads (15%) | called by muse, mutect2, varscan2
- MAP1B | c.3771G>A p.P1257= | Silent (SNP) | VAF 24/180 reads (13%) | catalogued as rs757277389, COSV57095053; called by muse, mutect2, varscan2
- MSTO1 | c.417C>G p.G139= | Silent (SNP) | VAF 12/111 reads (11%) | called by mutect2, varscan2
- SIL1 | c.1209C>T p.V403= | Silent (SNP) | VAF 67/455 reads (15%) | catalogued as CX155264; called by muse, mutect2, varscan2
- SLC13A5 | c.1458T>C p.N486= | Silent (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2
- WDR54 | c.730C>T p.L244= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- XRRA1 | c.1809G>A p.R603= | Silent (SNP) | VAF 29/272 reads (11%) | catalogued as rs766432171; called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.711C>T | RNA (SNP) | VAF 22/211 reads (10%) | called by muse, mutect2, varscan2
- COL1A1 | c.903+36C>T | Intron (SNP) | VAF 19/458 reads (4%) | catalogued as rs1045352552; called by muse, mutect2
- ERLIN2 | c.425-1618C>A | Intron (SNP) | VAF 40/337 reads (12%) | called by muse, mutect2, varscan2
- GABRA1 | c.-16+582A>T | Intron (SNP) | VAF 23/148 reads (16%) | called by muse, mutect2, varscan2
- LDLRAD2 | c.*2295del | 3'UTR (DEL) | VAF 72/480 reads (15%) | called by mutect2, pindel, varscan2
- NSMCE4A | c.845-572C>T | Intron (SNP) | VAF 6/52 reads (12%) | catalogued as rs1214436705; called by muse, mutect2, varscan2
- ZIK1 | c.-41G>A | 5'UTR (SNP) | VAF 12/86 reads (14%) | catalogued as rs896638868; called by muse, mutect2, varscan2
